Surgical pathology report (de-identified scan), TCGA case TCGA-E5-A4U1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Roswell Park, specimen TCGA-E5-A4U1-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S):

A. TURBT LEFT WALL BLADDER

B. TURBT DEEP BITES LEFT WALL

C. TURBT BLADDER NECK

D. TURBT PROSTATIC URETHRA

ICD-0-3

Carcinoma, urothelial, nos 8120/3

Site: bladder, wall nos C67.9

CLINICAL HISTORY:

TURBT

*pw
10/10/12*

PRE-OPERATIVE DIAGNOSIS:

Bladder cancer

GROSS DESCRIPTION:

A. TURBT LEFT WALL BLADDER

Received fresh labeled with the patient's identification and "left wall bladder" aggregate of pink-tan friable tissue chips weighing 4.98 g and measuring 3.5 x 2.5 x 1.3 cm; tissue is procured and the remainder submitted entirely in cassettes A1-A4.

B. TURBT DEEP BITES LEFT WALL

Received fresh labeled with the patient's identification and "deep bite left wall" are pink-tan tissue chips in aggregate weighing 0.33 g and measuring 2.1 x 1.7 x 0.5 cm. They are bisected and a portion is submitted for tissue procurement; remainder submitted entirely in cassette B1.

C. TURBT BLADDER NECK

Received fresh labeled with the patient's identification and "bladder neck" are pink-tan tissue chips in aggregate weighing 0.59 g and measuring 2.2 x 1.4 x 0.6 cm. A portion is submitted for tissue procurement and the remainder submitted entirely in cassette C1.

D. TURBT PROSTATIC URETHRA

Received fresh labeled with the patient's identification and "prostate urethra" are pink-tan tissue chips in aggregate weighing 0.15 g and measuring 1.5 x 0.8 x 0.5 cm. The largest piece is bisected and is submitted for tissue procurement; remainder submitted entirely in cassette D1.

[page 2 of 2]
DIAGNOSIS:

A. BLADDER, LEFT WALL, TRANSURETHRAL RESECTION:

- INVASIVE UROTHELIAL CELL CARCINOMA, HIGH GRADE
- INVADING INTO THE MUSCULARIS PROPRIA
- SUSPICIOUS FOR ANGIOLYMPHATIC INVASION

B. BLADDER, LEFT WALL, TRANSURETHRAL RESECTION:

- INVASIVE UROTHELIAL CELL CARCINOMA, HIGH GRADE
- INVADING INTO THE MUSCULARIS PROPRIA

C. BLADDER, NECK, TRANSURETHRAL RESECTION:

- PAPILLARY UROTHELIAL CELL CARCINOMA, HIGH GRADE
- NO INVASION IDENTIFIED

D. URETHRA, PROSTATIC, TRANSURETHRAL RESECTION:

- URETHRA DENUDED OF MUCOSA
- NO MALIGNANCY IDENTIFIED

	Yes	No
1. Is there a discrepancy?		
2. Is there a date discrepancy?		
3. Is there a policy discrepancy?		
4. Is there a history discrepancy?		
5. Is there a primary noted discrepancy?		
6. Is there a secondary noted discrepancy?		
7. Is there a tertiary noted discrepancy?		
8. Is there a quaternary noted discrepancy?		
9. Is there a quinary noted discrepancy?		
10. Is there a senary noted discrepancy?		
11. Is there a septenary noted discrepancy?		
12. Is there an octenary noted discrepancy?		
13. Is there a nonary noted discrepancy?		
14. Is there a decenary noted discrepancy?		
15. Is there an undecenary noted discrepancy?		
16. Is there a duodecenary noted discrepancy?		
17. Is there a tredecenary noted discrepancy?		
18. Is there a quattuordecenary noted discrepancy?		
19. Is there a quindecenary noted discrepancy?		
20. Is there a sexdecenary noted discrepancy?		
21. Is there a septendecenary noted discrepancy?		
22. Is there an octodecenary noted discrepancy?		
23. Is there a nonadecenary noted discrepancy?		
24. Is there a vigintenary noted discrepancy?		
25. Is there a unguicentenary noted discrepancy?		
26. Is there a duocentenary noted discrepancy?		
27. Is there a tricentenary noted discrepancy?		
28. Is there a quadricentenary noted discrepancy?		
29. Is there a quingentenary noted discrepancy?		
30. Is there a sesquicentenary noted discrepancy?		
31. Is there a millicentenary noted discrepancy?		
32. Is there a millicentenary noted discrepancy?		
33. Is there a millicentenary noted discrepancy?		
34. Is there a millicentenary noted discrepancy?		
35. Is there a millicentenary noted discrepancy?		
36. Is there a millicentenary noted discrepancy?		
37. Is there a millicentenary noted discrepancy?		
38. Is there a millicentenary noted discrepancy?		
39. Is there a millicentenary noted discrepancy?		
40. Is there a millicentenary noted discrepancy?		
41. Is there a millicentenary noted discrepancy?		
42. Is there a millicentenary noted discrepancy?		
43. Is there a millicentenary noted discrepancy?		
44. Is there a millicentenary noted discrepancy?		
45. Is there a millicentenary noted discrepancy?		
46. Is there a millicentenary noted discrepancy?		
47. Is there a millicentenary noted discrepancy?		
48. Is there a millicentenary noted discrepancy?		
49. Is there a millicentenary noted discrepancy?		
50. Is there a millicentenary noted discrepancy?		
51. Is there a millicentenary noted discrepancy?		
52. Is there a millicentenary noted discrepancy?		
53. Is there a millicentenary noted discrepancy?		
54. Is there a millicentenary noted discrepancy?		
55. Is there a millicentenary noted discrepancy?		
56. Is there a millicentenary noted discrepancy?		
57. Is there a millicentenary noted discrepancy?		
58. Is there a millicentenary noted discrepancy?		
59. Is there a millicentenary noted discrepancy?		
60. Is there a millicentenary noted discrepancy?		
61. Is there a millicentenary noted discrepancy?		
62. Is there a millicentenary noted discrepancy?		
63. Is there a millicentenary noted discrepancy?		
64. Is there a millicentenary noted discrepancy?		
65. Is there a millicentenary noted discrepancy?		
66. Is there a millicentenary noted discrepancy?		
67. Is there a millicentenary noted discrepancy?		
68. Is there a millicentenary noted discrepancy?		
69. Is there a millicentenary noted discrepancy?		
70. Is there a millicentenary noted discrepancy?		
71. Is there a millicentenary noted discrepancy?		
72. Is there a millicentenary noted discrepancy?		
73. Is there a millicentenary noted discrepancy?		
74. Is there a millicentenary noted discrepancy?		
75. Is there a millicentenary noted discrepancy?		
76. Is there a millicentenary noted discrepancy?		
77. Is there a millicentenary noted discrepancy?		
78. Is there a millicentenary noted discrepancy?		
79. Is there a millicentenary noted discrepancy?		
80. Is there a millicentenary noted discrepancy?		
81. Is there a millicentenary noted discrepancy?		
82. Is there a millicentenary noted discrepancy?		
83. Is there a millicentenary noted discrepancy?		
84. Is there a millicentenary noted discrepancy?		
85. Is there a millicentenary noted discrepancy?		
86. Is there a millicentenary noted discrepancy?		
87. Is there a millicentenary noted discrepancy?		
88. Is there a millicentenary noted discrepancy?		
89. Is there a millicentenary noted discrepancy?		
90. Is there a millicentenary noted discrepancy?		
91. Is there a millicentenary noted discrepancy?		
92. Is there a millicentenary noted discrepancy?		
93. Is there a millicentenary noted discrepancy?		
94. Is there a millicentenary noted discrepancy?		
95. Is there a millicentenary noted discrepancy?		
96. Is there a millicentenary noted discrepancy?		
97. Is there a millicentenary noted discrepancy?		
98. Is there a millicentenary noted discrepancy?		
99. Is there a millicentenary noted discrepancy?		
100. Is there a millicentenary noted discrepancy?		

Source: NCI Genomic Data Commons file 8239d631-89ab-4bfc-aedf-429495d35caa (TCGA-E5-A4U1.0010AA87-DA61-42F2-8A3D-49DCDDB7484C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).